TCGA case TCGA-G4-6314 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/abe658e0-33f9-4f57-849b-dec4d20964d6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Alive.

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 76.5 years (27,958 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,093 days (3.0 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 50; Lymph nodes tested: 59; Lymphatic invasion present: Yes; Non nodal tumor deposits: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 48 days; Days to treatment end: 209 days; Number of cycles: 12; Treatment dose: 8,976 mg; Prescribed dose: 756; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 48 days; Days to treatment end: 181 days; Number of cycles: 10; Treatment dose: 1,577 mg; Prescribed dose: 160; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 103 days; Days to treatment end: 209 days; Number of cycles: 8; Treatment dose: 6,000 mg; Prescribed dose: 752; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 337 days; Days to treatment end: 561 days (1.5 years); Number of cycles: 17; Treatment dose: 6,404 mg; Prescribed dose: 386; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 337 days; Days to treatment end: 561 days (1.5 years); Number of cycles: 17; Treatment dose: 3,874 mg; Prescribed dose: 240; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin; Initial disease status: Progressive Disease; Days to treatment start: 337 days; Days to treatment end: 561 days (1.5 years); Number of cycles: 17; Treatment dose: 12,464 mg; Prescribed dose: 740; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 609 days (1.7 years); Days to treatment end: 622 days (1.7 years); Treatment dose: 3,000 cGy; Course number: 1; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Recurrent Disease; Days to treatment start: 841 days (2.3 years); Days to treatment end: 841 days (2.3 years); Course number: 2; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 898 days (2.5 years); Days to treatment end: 911 days (2.5 years); Treatment dose: 3,000 cGy; Course number: 3; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Initial disease status: Progressive Disease; Days to treatment start: 954 days (2.6 years); Days to treatment end: 1,045 days (2.9 years); Number of cycles: 7; Treatment dose: 5,765 mg; Prescribed dose: 825; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 954 days (2.6 years); Days to treatment end: 1,045 days (2.9 years); Number of cycles: 7; Treatment dose: 1,085 mg; Prescribed dose: 165; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 1,093 days (3.0 years); Days to treatment end: 1,093 days (3.0 years); Course number: 4; Treatment anatomic sites: Distant Site.
2. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 76.6 years (27,996 days); Days to diagnosis: 38 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 78.2 years (28,563 days); Days to diagnosis: 605 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS.

Follow-up (4 entries)
- Day 38 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 38 days.
- Day 605 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 605 days (1.7 years).
- Days to follow up: 1,031 days (2.8 years); Disease response: With Tumor.
- Days to follow up: 1,093 days (3.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- KRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 84.1 kg; Height: 158.5 cm; BMI: 33.5.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G4-6314-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-G4-6314-01A-01-BS1: Section location: Bottom; Percent tumor cells: 35; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 60.
  Slide TCGA-G4-6314-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25.
- Sample TCGA-G4-6314-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G4-6314-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-G4-6314-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 0.9; Shortest dimension: 0.7.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: Yes; KRAS mutation found: No; BRAF gene analysis indicator: Yes; History colon polyps: No; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Regimen number: 2.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 4; Therapy regimen: Progression.
- Drug treatment 3: Regimen number: 3; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 1.
- Radiation treatment 1: Radiation type other: Gamma Knife Stereotactic radiosurgery; Therapy regimen: Recurrence.
- Radiation treatment 2: Radiation type other: Gamma Knife Stereotactic radiosurgery; Therapy regimen: Progression.
- Follow-up form 1: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bladder.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -430.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Locoregional.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy bladder cancer treated with unknown locoregional pharmaceuticals and radiation.
- Prior malignancy: Prior malignancy bladder cancer treated with unknown locoregional pharmaceuticals and radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,093 days; disease-specific survival: no event (censored), 1,093 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 38 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-G4-6314-01): tumor purity 0.51, ploidy 3.3, whole-genome doublings 1 (call status: legacy_call).
